Gene-level copy-number profile of tumor specimen ALCH-B0CA-TTP1-A from ALCHEMIST case ALCH-B0CA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.7 years (20,726 days).
Specimen ALCH-B0CA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 439f4941-f1c8-412c-b9f6-3d92946c5e48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/464a71f8-2bea-4c11-87c1-315c3c4fde9b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 113; copy number 2: 13,331; copy number 3: 3,359; copy number 4: 35,307; copy number 5: 1,193; copy number 6: 5,520; copy number 7: 61; copy number 8: 2; copy number 9: 1; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:66,075,800–66,094,697, 1 gene (within-gene range 0–4): ASL.
- chr14:73,237,497–73,274,640, 4 genes (within-gene range 0–4): PAPLN, AC004846.1, RNU6-419P, AC004846.2.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–3): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,461,221–143,500,512, 4 genes, copy number 20: AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr17:17,476,994–17,493,221, 1 gene, copy number 9: MED9.

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
